CCDI case PBCLEK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/69b6a01e-ee9e-4eff-8c2f-bdca23425a5f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.6 years (3,144 days).

Biospecimens (3 samples)
- Sample 0DV4IP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV4IY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV4KT: Tissue type: Tumor; Specimen type: Solid Tissue.
